Gene-level copy-number profile of tumor specimen C3L-06356-54 from CPTAC case C3L-06356, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 70.3 years (25,686 days).
Specimen C3L-06356-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2fbfdd95-fb34-40e6-ab2a-ad5726feeae9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06356-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/44892f7a-7f3b-44c7-919c-c370fcdfd99f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 3,188; copy number 2: 55,697; copy number 3: 16; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:49,188,736–49,274,600, 4 genes (within-gene range 0–2): TUBA1C, Metazoa_SRP, AC010173.1, AC125611.3.
- chr15:75,023,586–75,121,666, 4 genes: PPCDC, AC113208.2, Metazoa_SRP, AC113208.1.
- chr17:32,324,431–32,360,700, 1 gene (within-gene range 0–2): AC005899.4.
- chr17:32,343,528–32,412,420, 6 genes (within-gene range 0–2): OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 332. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
